Somatic mutation profile of tumor specimen TARGET-30-PATYWX-01A (aliquot TARGET-30-PATYWX-01A-01D) from TARGET case TARGET-30-PATYWX, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 4.0 years (1,461 days).
Specimen TARGET-30-PATYWX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d28b3ab-592d-4445-8b04-a0744bfd7921.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATYWX-10A (Blood Derived Normal), aliquot TARGET-30-PATYWX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aaab18bc-dca7-4251-92f0-6d792925d1d6

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MLLT10 | c.2015G>A p.R672H (on ENST00000307729 / NM_001195626.3; = p.R688H on NM_004641.3) | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs755064344, COSV57001460; called by muse, mutect2, varscan2
- NPAP1 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV61505376; called by muse, mutect2, varscan2
- PRKDC | c.3463C>T p.R1155* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as rs867149509, COSV58046180; called by muse, mutect2, varscan2
- ATXN1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- CREBBP | c.*453T>C | 3'UTR (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- CSPG4 | c.*139G>T | 3'UTR (SNP) | VAF 15/49 reads (31%) | catalogued as COSV57895899; called by muse, mutect2, varscan2
